Somatic mutation profile of tumor specimen TARGET-30-PASLRM-01A (aliquot TARGET-30-PASLRM-01A-01D) from TARGET case TARGET-30-PASLRM, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 1.6 years (591 days).
Specimen TARGET-30-PASLRM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c2d47a9-fa71-470f-90b7-4f84b9e370d5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASLRM-10A (Blood Derived Normal), aliquot TARGET-30-PASLRM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4627870-ca96-467d-87a6-2abead2fefc0

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLLT1 | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV53134168; called by muse, mutect2, varscan2
- NCAM1 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57528113; called by muse, mutect2, varscan2
- TET2 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs776272021, COSV54439006; called by muse, mutect2, varscan2
